Somatic mutation profile of tumor specimen C3L-06115-01 (aliquot CPT0334850006) from CPTAC case C3L-06115, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.2 years (23,079 days).
Specimen C3L-06115-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3afadfa8-0e8d-444a-b009-1641e76d8213.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06115-31 (Blood Derived Normal), aliquot CPT0334830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84265e4e-1dd7-40c6-b644-01ed946a04ba

The open-access MAF lists 720 somatic variants for this specimen: 446 protein-altering or splice-affecting, 250 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 406, Silent 250, Nonsense Mutation 21, Splice Region 11, Intron 11, Splice Site 5, 3'Flank 3, 5'Flank 3, 3'UTR 3, RNA 3, Translation Start Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 88/216 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 167/359 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12667G>A p.G4223R | Missense Mutation (SNP) | VAF 26/618 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101291466; called by muse, mutect2
- ABCA6 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | catalogued as rs754745012; called by muse, mutect2, varscan2
- ACSM2B | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100312234; called by muse, mutect2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 145/388 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- ADGRF1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 23/742 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1432137596; called by muse, mutect2
- ADGRF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 269/419 reads (64%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV51950717; called by muse, mutect2, varscan2
- ADNP | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.935); catalogued as rs760486899; called by muse, mutect2
- AFAP1 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs767988954, COSV61794295; called by muse, mutect2, varscan2
- AFF2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 199/267 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV100650376; called by muse, mutect2, varscan2
- AGTR2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs1556673780, COSV64156255; called by muse, mutect2
- AKAP6 | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 138/374 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1472135012, COSV55226177; called by muse, mutect2
- ALPK1 | c.626T>G p.M209R | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1471815576; called by muse, varscan2
- AP3D1 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1380225381; called by muse, mutect2, varscan2
- ARHGAP1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs764362910, COSV61735207; called by muse, mutect2, varscan2
- ARMC4 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV59467087; called by muse, mutect2, varscan2
- ATG9B | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs943355065; called by muse, mutect2, varscan2
- ATN1 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 145/601 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1305183544, COSV63110829; called by muse, mutect2, varscan2
- BRD3 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1217352212, COSV57703923; called by muse, mutect2, varscan2
- CACNA1C | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 340/552 reads (62%) | catalogued as rs1555600007; called by muse, mutect2
- CACNA1G | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs1468956826; called by muse, mutect2, varscan2
- CATSPER1 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 188/495 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202130764; called by muse, mutect2, varscan2
- CATSPER2 | c.1285G>A p.E429K (on ENST00000321596 / NM_001282309.3; = p.E431K on NM_172095.4) | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58660346; called by muse, mutect2, varscan2
- CCDC54 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as COSV99660348; called by muse, mutect2
- CCDC60 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV100555555; called by muse, mutect2
- CD48 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 125/447 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs753317595, COSV63566089; called by muse, mutect2, varscan2
- CHRNA4 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64718128; called by muse, mutect2
- CHST9 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.046); catalogued as rs200160632; called by muse, varscan2
- CLCN1 | c.2403G>A p.E801= | Splice Region (SNP) | VAF 111/361 reads (31%) | catalogued as COSV100578230; called by muse, mutect2, varscan2
- CLEC10A | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.897); catalogued as COSV99644871; called by muse, mutect2, varscan2
- CLIC3 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 195/403 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV65406656; called by muse, mutect2, varscan2
- CLRN2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 142/404 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs758709903, COSV71825283; called by muse, mutect2, varscan2
- CNDP1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 137/353 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs539490484, COSV62595630; called by muse, mutect2, varscan2
- CNGB3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 302/496 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100182089, COSV60693774; called by muse, mutect2, varscan2
- CNTN4 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1454984994; called by muse, mutect2, varscan2
- CNTNAP1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 203/518 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs755070825, COSV99226140, COSV99226997; called by muse, mutect2, varscan2
- COL21A1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280324762; called by muse, mutect2, varscan2
- COL4A1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 147/375 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1427241377, COSV99059036; called by muse, mutect2
- COL5A1 | c.4919A>G p.K1640R | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as CD133007; called by muse, mutect2
- COL5A1 | c.5186C>A p.T1729N | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); catalogued as rs955493186; called by muse, mutect2, varscan2
- CRAMP1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 157/430 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV51962200; called by muse, mutect2, varscan2
- CRB2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 115/250 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as rs1564371983; called by muse, mutect2, varscan2
- CRNN | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 206/818 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV55122932; called by muse, mutect2, varscan2
- CRYBB1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 141/480 reads (29%) | catalogued as rs141811471, COSV53234605; called by muse, mutect2, varscan2
- CSMD3 | c.9737G>A p.G3246E (on ENST00000297405 / NM_001363185.1; = p.G3077E on NM_052900.3) | Missense Mutation (SNP) | VAF 100/620 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112678; called by muse, mutect2, varscan2
- CSMD3 | c.7925G>A p.G2642E (on ENST00000297405 / NM_001363185.1; = p.G2538E on NM_052900.3) | Missense Mutation (SNP) | VAF 290/458 reads (63%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.984); catalogued as COSV52128481; called by muse, mutect2, varscan2
- CSMD3 | c.3749G>T p.G1250V (on ENST00000297405 / NM_001363185.1; = p.G1146V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52174808; called by muse, mutect2
- CUX1 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 157/454 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99470348; called by muse, mutect2, varscan2
- CYP2B6 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as rs1183374846, COSV57843755; called by muse, mutect2, varscan2
- CYP2B6 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV57844825; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 82/257 reads (32%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DNAH12 | c.3619C>T p.R1207C (on ENST00000351747; = p.R1230C on NM_001366028.2) | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs191653485, COSV61058453; called by muse, mutect2, varscan2
- DSCAM | c.3361C>T p.L1121F | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1379697712, COSV101261698, COSV68024223; called by muse, mutect2, varscan2
- DUOXA1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 128/340 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs147223934, COSV50993544; called by muse, mutect2, varscan2
- EFCAB8 | c.1449C>T p.I483= | Splice Region (SNP) | VAF 73/198 reads (37%) | catalogued as rs1190346730, COSV101267290; called by muse, mutect2, varscan2
- EPHA6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67585203; called by muse, mutect2, varscan2
- ESYT3 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs887222585; called by muse, mutect2, varscan2
- FAM189A1 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 43/475 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs570961907; called by muse, mutect2
- FARP2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1172435178, COSV50877786; called by muse, mutect2, varscan2
- FBXO24 | c.1145G>A p.G382E (on ENST00000241071 / NM_033506.3; = p.G420E on NM_012172.5) | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601177; called by muse, mutect2, varscan2
- FER1L5 | c.1196C>T p.S399F (on ENST00000623019; = p.S416F on NM_001293083.2) | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1456482802; called by muse, mutect2, varscan2
- FLG | c.7310G>A p.G2437E | Missense Mutation (SNP) | VAF 70/845 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs575169730; called by muse, mutect2
- FLG | c.5947G>A p.E1983K | Missense Mutation (SNP) | VAF 393/730 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV64239821, COSV64240367, COSV64242648; called by muse, mutect2, varscan2
- FLT1 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 120/374 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56735152; called by muse, mutect2, varscan2
- FPR3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59332104; called by muse, mutect2
- FRMD7 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 201/252 reads (80%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100048848; called by muse, mutect2, varscan2
- FRMPD1 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV100899618, COSV66699743; called by muse, mutect2, varscan2
- FRMPD4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as rs1353864168; called by muse, mutect2, varscan2
- FUT9 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56150853; called by muse, mutect2, varscan2
- GBE1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs183019204, COSV101450122; called by muse, mutect2, varscan2
- GLI2 | c.2236G>A p.G746R (on ENST00000361492 / NM_001374353.1; = p.G763R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58053248; called by muse, mutect2, varscan2
- GLRB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 141/407 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868460883, COSV52413855, COSV52423095; called by muse, mutect2, varscan2
- GPR101 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 207/273 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981584; called by muse, mutect2, varscan2
- GPR63 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV57743588; called by muse, mutect2
- GRIA1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV53608602; called by muse, mutect2, varscan2
- GUCY1A2 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56480614; called by muse, mutect2, varscan2
- GUCY2C | c.1750T>C p.F584L | Missense Mutation (SNP) | VAF 186/346 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV99663614; called by muse, mutect2, varscan2
- HABP2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV63491328; called by muse, mutect2, varscan2
- HCFC1 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 273/332 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV60068994; called by muse, mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by muse, mutect2
- HCRTR2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 267/397 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs758357339; called by muse, mutect2, varscan2
- HDAC10 | c.1060T>C p.W354R | Missense Mutation (SNP) | VAF 250/439 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478937189; called by muse, mutect2, varscan2
- IFNLR1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 67/493 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV59527576; called by muse, mutect2, varscan2
- IGHD3-9 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 102/278 reads (37%) | catalogued as rs782434392; called by muse, mutect2
- IGHV2-26 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782599020; called by muse, mutect2, varscan2
- IGHV4-39 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1421125695; called by muse, varscan2
- IL1R1 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 19/363 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52105577; called by muse, mutect2
- IRX2 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 15/526 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1335724723; called by muse, mutect2
- ITGB6 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1559238240, COSV51798946; called by muse, mutect2, varscan2
- KCND2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 110/346 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs757409386, COSV58592426; called by muse, mutect2, varscan2
- KRI1 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 162/487 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1206267033; called by muse, mutect2, varscan2
- KRT79 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 140/217 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57940000, COSV57941402; called by muse, mutect2, varscan2
- LAMA3 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 154/522 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100556697; called by muse, mutect2
- LAMA5 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 184/491 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs1238232872; called by muse, varscan2
- LIMK1 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs1554700589; called by muse, mutect2, varscan2
- LRRC56 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs749154374; called by muse, mutect2, varscan2
- LRRK2 | c.5326C>T p.L1776F | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV54157223; called by muse, mutect2, varscan2
- MAGEL2 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 153/419 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.728); catalogued as rs757987900, COSV58569698; called by muse, mutect2, varscan2
- ME3 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 41/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770717280, COSV62772613; called by muse, mutect2, varscan2
- MFF | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1208966544; called by muse, mutect2, varscan2
- MGAM | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as COSV101527513, COSV72075394; called by muse, mutect2, varscan2
- MMP20 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV52777635; called by muse, mutect2, varscan2
- MORC1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV99224965, COSV99226837; called by muse, mutect2, varscan2
- MPDZ | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CD117305; called by muse, mutect2, varscan2
- MSH4 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV54197607; called by muse, mutect2, varscan2
- MUC16 | c.39689G>A p.G13230E | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs779819700; called by muse, mutect2, varscan2
- MUC22 | c.2614G>A p.G872S | Missense Mutation (SNP) | VAF 271/1277 reads (21%) | SIFT tolerated (0.74); catalogued as rs533911260; called by muse, mutect2, varscan2
- MUC5B | c.11540C>T p.T3847I | Missense Mutation (SNP) | VAF 21/688 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs1430433077; called by muse, mutect2
- MYCBPAP | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1030452443, COSV60412316; called by muse, mutect2, varscan2
- MYH2 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV55433573; called by muse, mutect2, varscan2
- MYH6 | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs755785767; called by muse, mutect2
- MYT1 | c.2704G>A p.G902S | Missense Mutation (SNP) | VAF 19/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752600921, COSV60500921; called by muse, mutect2
- MYT1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 213/581 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV60504988; called by muse, mutect2, varscan2
- NAT16 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 195/464 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1326961991; called by muse, mutect2, varscan2
- NLRP5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs267605707, COSV66761742; called by muse, mutect2, varscan2
- NLRP8 | c.370A>C p.I124L | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52590257; called by muse, mutect2, varscan2
- OR10K1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 160/618 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs188612034, COSV56870795, COSV56872483; called by muse, mutect2, varscan2
- OR2M5 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 270/537 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63545545, COSV63546003; called by muse, mutect2, varscan2
- OR4A16 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV59043201; called by muse, mutect2, varscan2
- OR4B1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV58884275; called by muse, mutect2, varscan2
- OR4K17 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 127/315 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1352785041, COSV59648122; called by muse, mutect2, varscan2
- OR4X2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 138/390 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166747967, COSV56582293; called by muse, mutect2, varscan2
- OR51G2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58992960; called by muse, mutect2, varscan2
- OR52J3 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 164/416 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV66747019; called by muse, mutect2, varscan2
- OR5D13 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV62332993; called by muse, mutect2, varscan2
- OR5J2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 115/348 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100398897, COSV100399206; called by muse, mutect2, varscan2
- OR9K2 | c.683C>T p.S228L (on ENST00000305377; = p.S206L on NM_001005243.1) | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs368474784; called by muse, mutect2
- OTUB2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 21/418 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.731); catalogued as rs763476677; called by muse, mutect2
- PCDHA13 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs994931084, COSV56494356; called by muse, mutect2
- PCDHGB1 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs764844897, COSV54051537; called by muse, mutect2, varscan2
- PCDHGB4 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV53963523; called by muse, mutect2, varscan2
- PCGF5 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.503); catalogued as rs1285438472; called by muse, mutect2, varscan2
- PCGF5 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV60237807; called by muse, mutect2, varscan2
- PCNX4 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs747824903; called by muse, mutect2, varscan2
- PIGQ | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 24/393 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50313863; called by muse, mutect2
- PKHD1 | c.10240A>T p.I3414F | Missense Mutation (SNP) | VAF 414/528 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as CD032489; called by muse, mutect2, varscan2
- POF1B | c.726G>A p.V242= | Splice Region (SNP) | VAF 96/132 reads (73%) | catalogued as rs879091306, COSV99427446; called by muse, mutect2, varscan2
- PPDPFL | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as rs528096043; called by muse, mutect2
- PPP1R3A | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 139/398 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs368610339, COSV52880676; called by muse, mutect2, varscan2
- PRAMEF14 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs2797741; called by muse, mutect2
- PRDM8 | c.1811A>G p.Q604R | Missense Mutation (SNP) | VAF 163/387 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1560480745; called by muse, mutect2, varscan2
- PROP1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 152/392 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57645281; called by muse, mutect2, varscan2
- PRR23A | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 160/415 reads (39%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); catalogued as rs773362938; called by muse, mutect2, varscan2
- PSG7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68444549; called by muse, mutect2, varscan2
- PTPRD | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1273962518, COSV61937727; called by muse, mutect2, varscan2
- PTPRD | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV61936192, COSV61975980; called by muse, mutect2, varscan2
- QRFPR | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 65/484 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.869); catalogued as rs747943209, COSV57675341; called by muse, mutect2, varscan2
- QRFPR | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 205/574 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs541376457, COSV57675716; called by muse, mutect2, varscan2
- QRICH2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as rs907445932, COSV53152379; called by muse, mutect2, varscan2
- REG1B | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.42); catalogued as COSV100521473; called by muse, mutect2, varscan2
- REXO1 | c.3499C>T p.H1167Y | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749820997, COSV50076575; called by muse, mutect2, varscan2
- RNF220 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100698550; called by muse, mutect2, varscan2
- RP1L1 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 166/244 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101223015; called by muse, mutect2, varscan2
- RSBN1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1217742673; called by muse, mutect2
- SAFB2 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV53043600; called by muse, mutect2, varscan2
- SALL1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV51754140; called by muse, mutect2
- SAMD15 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV53626030; called by muse, mutect2
- SAMD9L | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 123/309 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59086082; called by muse, mutect2, varscan2
- SCARB2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs1316817158; called by muse, mutect2, varscan2
- SCLY | c.1135C>T p.H379Y (on ENST00000651534; = p.H371Y on NM_016510.7) | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1317705600; called by muse, mutect2, varscan2
- SGO2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 102/252 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs766342242, COSV63413945; called by muse, mutect2, varscan2
- SLA2 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1315277424; called by muse, mutect2, varscan2
- SLC22A23 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1305855138; called by muse, mutect2
- SLC22A24 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371518525, COSV70301809; called by muse, mutect2, varscan2
- SLC36A2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 154/364 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100079497; called by muse, mutect2, varscan2
- SLC38A4 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 82/450 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.333); catalogued as rs866244664, COSV56967635; called by muse, mutect2, varscan2
- SLC47A2 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 86/302 reads (28%) | catalogued as rs1464285400; called by muse, mutect2, varscan2
- SNAP91 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52118664; called by muse, mutect2, varscan2
- SNAP91 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52117679; called by muse, mutect2, varscan2
- SNAP91 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52118402; called by muse, mutect2, varscan2
- SORCS2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs747884144, COSV61162520; called by muse, mutect2, varscan2
- SP140L | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54746268; called by muse, mutect2, varscan2
- SPRR1B | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 254/876 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61067429, COSV61068080; called by muse, mutect2
- SPTA1 | c.5941C>T p.Q1981* | Nonsense Mutation (SNP) | VAF 173/348 reads (50%) | catalogued as COSV100934162; called by muse, mutect2
- SRCAP | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 187/508 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs781603720, COSV99350618; called by muse, mutect2, varscan2
- SRGAP1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 150/1644 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV61894969; called by muse, mutect2
- SRRT | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 10/351 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53822489, COSV99574052; called by muse, mutect2
- ST6GAL2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 20/272 reads (7%) | PolyPhen possibly damaging (0.491); catalogued as rs1335982644, COSV64526291; called by muse, mutect2
- STK16 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 122/331 reads (37%) | catalogued as COSV50278857; called by muse, mutect2, varscan2
- TCF21 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 183/328 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs148497847; called by muse, mutect2, varscan2
- TCOF1 | c.1811C>T p.P604L (on ENST00000377797 / NM_001135243.1; = p.P527L on NM_000356.4) | Missense Mutation (SNP) | VAF 141/442 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs1393921661; called by muse, mutect2, varscan2
- TENM3 | c.7279C>T p.P2427S | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as rs762799784, COSV69305744; called by muse, mutect2, varscan2
- TET3 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs372536879; called by muse, mutect2, varscan2
- TEX13C | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs1159415981; called by muse, mutect2, varscan2
- TEX33 | c.302C>T p.S101F (on ENST00000381821 / NM_001163857.2; = p.S16F on NM_178552.4) | Missense Mutation (SNP) | VAF 18/638 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs1387450415, COSV67822927; called by muse, mutect2
- THAP8 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 200/499 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs770198368; called by muse, mutect2, varscan2
- THSD7B | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs867749859, COSV99746974; called by muse, mutect2, varscan2
- TINAG | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 482/606 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99449822; called by muse, mutect2, varscan2
- TMED3 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 98/264 reads (37%) | catalogued as rs149930590; called by muse, mutect2, varscan2
- TMEM132D | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752825227, COSV67158693; called by muse, mutect2
- TMPRSS4 | c.744-1G>A p.X248_splice | Splice Site (SNP) | VAF 112/280 reads (40%) | catalogued as COSV101449354; called by muse, mutect2, varscan2
- TNFSF10 | c.270G>A p.K90= | Splice Region (SNP) | VAF 39/264 reads (15%) | catalogued as rs760670084; called by muse, mutect2, varscan2
- TNRC6B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 340/555 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs766326541; called by muse, mutect2, varscan2
- TOPAZ1 | c.4604C>T p.S1535F | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as rs868619035, COSV59071039; called by muse, mutect2, varscan2
- TP63 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 160/418 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV53199759; called by muse, mutect2, varscan2
- TRIM49B | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs781386649; called by muse, mutect2, varscan2
- TRIM50 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 195/470 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs370311701; called by muse, mutect2, varscan2
- TRPC4 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58990158; called by muse, mutect2
- TTC13 | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs199970513, COSV100792865; called by muse, mutect2
- TTC6 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs764394901, COSV101606803; called by muse, varscan2
- TTN | c.25273C>T p.L8425F (on ENST00000591111; = p.L7498F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/214 reads (38%) | PolyPhen possibly damaging (0.663); catalogued as COSV60305775; called by muse, mutect2, varscan2
- UCHL1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 146/381 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs745355343; called by muse, mutect2, varscan2
- UGT2A1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 115/300 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1440167369, COSV54141322; called by muse, mutect2, varscan2
- UGT2B17 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58500989; called by muse, mutect2
- USH2A | c.8576G>A p.R2859H | Missense Mutation (SNP) | VAF 182/343 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as rs778272177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAV2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV64081150; called by muse, mutect2, varscan2
- VPREB1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 261/544 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs1207776261, COSV56426052; called by muse, mutect2
- WASHC2A | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1363279369; called by muse, mutect2, varscan2
- WDR62 | c.4115C>T p.A1372V | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.048); catalogued as COSV104373441; called by muse, mutect2, varscan2
- WDR87 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1371041062, COSV58192838; called by muse, mutect2, varscan2
- WFDC13 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57914925; called by muse, mutect2, varscan2
- WIPF3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.63); catalogued as COSV54210529; called by muse, mutect2, varscan2
- ZBED9 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 166/777 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773549282; called by muse, mutect2, varscan2
- ZFP2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374648668; called by muse, mutect2, varscan2
- ZNF20 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201734727, COSV61998926; called by muse, mutect2, varscan2
- ZNF286A | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 129/372 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as rs756583719, COSV67845084, COSV67845617; called by muse, mutect2, varscan2
- ZNF341 | c.2239C>T p.P747S (on ENST00000375200 / NM_001282935.1; = p.P740S on NM_032819.4) | Missense Mutation (SNP) | VAF 170/483 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs760837496, COSV100678157; called by muse, mutect2, varscan2
- ZNF486 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.062); catalogued as COSV58718842; called by muse, mutect2
- ZNF541 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54546966; called by muse, mutect2, varscan2
- ZNF667 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV52631011; called by muse, mutect2, varscan2
- ZNF667 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 105/309 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV52636358, COSV99410409; called by muse, mutect2, varscan2
- ZNF723 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as rs796317212; called by muse, mutect2, varscan2
- ZNF75D | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV66132511; called by muse, mutect2, varscan2
- ZNF843 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 77/573 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs781236692, COSV59847967; called by muse, mutect2, varscan2
- ZNF843 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 78/574 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV59847718; called by muse, mutect2, varscan2
- ZP4 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 259/471 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780075742, COSV63913782; called by muse, mutect2, varscan2
- ABCC2 | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2
- ABHD12B | c.433C>T p.L145F (on ENST00000337334 / NM_001206673.2; = p.L68F on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2
- AC008397.1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACAN | c.7448-1G>A p.X2483_splice (on ENST00000560601 / NM_001369268.1; = p.X2445_splice on NM_013227.3) | Splice Site (SNP) | VAF 104/285 reads (36%) | called by muse, mutect2, varscan2
- ACOD1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 19/403 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ACTL7B | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ADAM22 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- ADAMTS13 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY10 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 213/361 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ADGRG4 | c.4913C>T p.S1638F | Missense Mutation (SNP) | VAF 160/201 reads (80%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.10844C>T p.P3615L | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADGRV1 | c.11236G>A p.G3746R | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- AGAP2 | c.1259C>T p.S420L (on ENST00000547588 / NM_001122772.2; = p.S84L on NM_014770.4) | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.7445_7446dup p.E2483Lfs*6 | Frame Shift Ins (INS) | VAF 118/410 reads (29%) | called by mutect2, pindel, varscan2
- ALG8 | c.1451A>G p.K484R | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKFY1 | c.1147T>C p.F383L | Missense Mutation (SNP) | VAF 33/348 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); called by muse, mutect2
- ANLN | c.2441A>T p.K814I | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID2 | c.277_284+9del p.X93_splice | Splice Site (DEL) | VAF 56/124 reads (45%) | called by mutect2, pindel, varscan2
- ARMH4 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 133/323 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARNTL | c.1513G>A p.E505K (on ENST00000403290 / NM_001297719.2; = p.E504K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ATF7IP | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- BIRC6 | c.2457T>G p.N819K | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BOLL | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 38/331 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- BSN | c.6190G>A p.V2064M | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- C12orf4 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 13/380 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2
- C19orf81 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- C1QTNF5 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 192/517 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C1RL | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 147/456 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- C1orf226 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 325/616 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- C4orf51 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2
- CACNG3 | c.438G>A p.G146= | Splice Region (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- CAND2 | c.2870C>T p.A957V (on ENST00000456430 / NM_001162499.2; = p.A864V on NM_012298.3) | Missense Mutation (SNP) | VAF 152/415 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- CCDC150 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CCDC54 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.13); called by muse, mutect2
- CCDC93 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CENPE | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CENPQ | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.011); called by muse, mutect2
- CEP250 | c.4819C>G p.Q1607E | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CFAP54 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CFAP99 | c.835A>T p.I279F | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CHN1 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CHST9 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLCN7 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COG2 | c.1265C>G p.T422S | Missense Mutation (SNP) | VAF 107/409 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- COL11A1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CORO1A | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 145/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE5 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 112/636 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CRELD2 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 270/478 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CROT | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CSF2RB | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 128/493 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CT47B1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CWH43 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- DAGLA | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 26/610 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- DCHS2 | c.2046T>A p.F682L | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DCSTAMP | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 421/621 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DMRTC2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH12 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DNAH8 | c.10424G>A p.G3475D | Missense Mutation (SNP) | VAF 130/594 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.12892G>A p.D4298N | Missense Mutation (SNP) | VAF 247/412 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DNHD1 | c.8074G>A p.D2692N | Missense Mutation (SNP) | VAF 177/474 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DYSF | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2
- ECT2L | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2
- EFL1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 42/445 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.38); called by muse, mutect2
- EGFL6 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ELAPOR2 | c.2242G>A p.D748N (on ENST00000450689 / NM_001142749.3; = p.D581N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.572); called by muse, mutect2
- ELP1 | c.1432A>G p.R478G | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- ENPP4 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 133/665 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASN | c.5863C>T p.L1955F | Missense Mutation (SNP) | VAF 157/464 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW7 | c.1615G>A p.G539R (on ENST00000281708 / NM_001349798.2; = p.G459R on NM_018315.5) | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FER1L5 | c.4396G>A p.E1466K (on ENST00000623019; = p.E1439K on NM_001293083.2) | Missense Mutation (SNP) | VAF 120/333 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FIG4 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 154/237 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FMN2 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 140/558 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FXYD4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 89/301 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GABRE | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- GCNT7 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 91/273 reads (33%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- GTF2IRD1 | c.124-1G>A p.X42_splice | Splice Site (SNP) | VAF 85/210 reads (40%) | called by muse, mutect2, varscan2
- GTF3C4 | c.2313C>T p.L771= | Splice Region (SNP) | VAF 85/185 reads (46%) | called by muse, mutect2, varscan2
- GYS2 | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- HCN2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- HERC6 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 185/530 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIGD2B | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- IGSF9 | c.402A>C p.S134= | Splice Region (SNP) | VAF 112/397 reads (28%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGA11 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 28/413 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IZUMO1R | c.517C>T p.P173S (on ENST00000440961; = p.P180S on NM_001199206.3) | Missense Mutation (SNP) | VAF 68/481 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KAT6B | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNIP1 | c.277T>A p.F93I (on ENST00000411494 / NM_001034837.3; = p.F82I on NM_014592.4) | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK10 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 224/573 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM4E | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 18/461 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KISS1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 30/641 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.55); called by muse, mutect2
- KMT2B | c.7548C>T p.L2516= | Splice Region (SNP) | VAF 36/259 reads (14%) | called by muse, mutect2, varscan2
- KRR1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 93/489 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP9-4 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 269/660 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LMO7 | c.4907G>A p.G1636E (on ENST00000357063; = p.G1317E on NM_005358.5) | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB10 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MAGI2 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MALRD1 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAML1 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 174/444 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP2K2 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 157/463 reads (34%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2845C>T p.P949S (on ENST00000554752 / NM_001284230.1; = p.P963S on NM_033141.4) | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- MCF2L2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MECOM | c.1031C>T p.P344L (on ENST00000468789 / NM_001105078.4; = p.P532L on NM_004991.4) | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- MED14 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MKRN3 | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 18/540 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MROH5 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MS4A18 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MS4A6A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- MYH6 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MYLK | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 175/478 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MYO7A | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); called by muse, mutect2
- MYOM2 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- N4BP2 | c.4415T>A p.L1472* | Nonsense Mutation (SNP) | VAF 106/284 reads (37%) | called by muse, mutect2, varscan2
- NBEA | c.6884C>T p.S2295L | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NCR1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 204/547 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- NEDD4 | c.1011A>C p.E337D | Missense Mutation (SNP) | VAF 147/375 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NKG7 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 28/604 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- NLRP7 | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 80/689 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NME9 | c.770C>T p.A257V (on ENST00000333911 / NM_001349024.2; = p.A196V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/351 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NOBOX | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NONO | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 111/163 reads (68%) | called by muse, mutect2, varscan2
- NRROS | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 161/437 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- NSD1 | c.3719C>T p.S1240F | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2
- NUTM2B | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by mutect2, varscan2
- OCSTAMP | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR2A2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 123/339 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR2J2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 22/782 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR2T4 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 418/755 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4C6 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 120/369 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8H1 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 25/490 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- PCDH1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- PCK1 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 136/420 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- PDZD8 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PITPNM1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 176/495 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PKN1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 187/474 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLA2G2E | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEKHG4B | c.194C>T p.P65L (on ENST00000283426; = p.P421L on NM_052909.5) | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PPARD | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 76/897 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- PPFIA1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 15/420 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- PPP2R3B | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 208/612 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PRAM1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 192/523 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PRAMEF14 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 153/401 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRB4 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 230/903 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.071); called by muse, varscan2
- PRKCG | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 28/525 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2
- PRR22 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 44/619 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- PRR33 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTER | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2
- PTPRF | c.5395C>T p.Q1799* | Nonsense Mutation (SNP) | VAF 125/380 reads (33%) | called by muse, mutect2, varscan2
- PXDNL | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RAD21L1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- RBL2 | c.3085A>G p.M1029V | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFPL4A | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 108/434 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- RLF | c.3889G>A p.G1297R | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RNF115 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 80/335 reads (24%) | called by muse, mutect2, varscan2
- RP1 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SBF1 | c.3893C>T p.T1298I | Missense Mutation (SNP) | VAF 64/698 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2
- SDK2 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 175/477 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SEC31B | c.2344C>T p.H782Y | Missense Mutation (SNP) | VAF 134/338 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SEPTIN3 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 253/419 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SHANK2 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHH | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 158/441 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHISAL2A | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHKBP1 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC1 | c.5048C>T p.A1683V | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLC13A2 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC24A3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 129/379 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC25A26 | c.501C>T p.A167= | Splice Region (SNP) | VAF 104/293 reads (35%) | called by muse, mutect2, varscan2
- SLC35F6 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 15/480 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC6A11 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SLC6A13 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 59/673 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC6A14 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 92/130 reads (71%) | called by muse, mutect2, varscan2
- SLFN12L | c.1633G>A p.E545K (on ENST00000260908 / NM_001363830.1; = p.E563K on NM_001195790.1) | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SMC2 | c.1330T>A p.Y444N | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SMPDL3B | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOX8 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPON1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SSTR5 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 194/483 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SWT1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- SYNC | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 158/396 reads (40%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SYNE1 | c.4150G>A p.E1384K (on ENST00000367255 / NM_182961.4; = p.E1391K on NM_033071.3) | Missense Mutation (SNP) | VAF 90/137 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- TADA2B | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TECPR1 | c.734T>G p.V245G | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TECTA | c.5624G>A p.W1875* | Nonsense Mutation (SNP) | VAF 134/340 reads (39%) | called by muse, mutect2, varscan2
- TECTA | c.6435G>A p.W2145* | Nonsense Mutation (SNP) | VAF 13/260 reads (5%) | called by muse, mutect2
- TENM2 | c.2372G>A p.W791* (on ENST00000518659 / NM_001122679.2; = p.W559* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 13/402 reads (3%) | called by muse, mutect2
- TEX13C | c.2511G>A p.M837I | Missense Mutation (SNP) | VAF 178/233 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TG | c.5911C>T p.Q1971* | Nonsense Mutation (SNP) | VAF 40/722 reads (6%) | called by muse, mutect2
- TIGD2 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TLR2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 129/338 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFAIP2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFSF10 | c.270+1G>A p.X90_splice | Splice Site (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- TNS3 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 68/479 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAV8-1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TRAV9-1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM15 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 26/927 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2
- TRMT6 | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPC4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TSHZ2 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC37 | c.3294A>T p.E1098D | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TTN | c.74189A>C p.E24730A (on ENST00000591111; = p.E17306A on NM_003319.4) | Missense Mutation (SNP) | VAF 124/340 reads (36%) | PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TVP23C | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2
- TYK2 | c.3422C>T p.P1141L | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UGT1A6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- UNC13A | c.2932T>G p.F978V | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- UNC45B | c.1152G>T p.T384= | Splice Region (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- UNC79 | c.23T>C p.F8S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP4 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- VPS13B | c.10285C>T p.P3429S | Missense Mutation (SNP) | VAF 43/709 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- VPS50 | c.2522T>G p.L841W | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VWF | c.6692C>T p.P2231L | Missense Mutation (SNP) | VAF 139/570 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZEB1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM2 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 235/360 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZFYVE16 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF462 | c.1232T>G p.L411R | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZNF469 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ZNF580 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 25/540 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZNF99 | c.1142T>A p.L381* | Nonsense Mutation (SNP) | VAF 153/402 reads (38%) | called by muse, mutect2, varscan2
- AADACL3 | c.546G>A p.V182= | Silent (SNP) | VAF 128/397 reads (32%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1068G>A p.K356= | Silent (SNP) | VAF 279/507 reads (55%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.2694C>T p.T898= | Silent (SNP) | VAF 20/414 reads (5%) | catalogued as rs1325729441; called by muse, mutect2
- ADAMTS18 | c.1689G>A p.G563= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs1442515046, COSV51399231; called by muse, mutect2
- ADCY1 | c.951C>T p.S317= | Silent (SNP) | VAF 155/430 reads (36%) | called by muse, mutect2, varscan2
- ADCY10 | c.1185C>T p.I395= | Silent (SNP) | VAF 267/480 reads (56%) | catalogued as rs757261904, COSV63238799; called by muse, mutect2, varscan2
- ADCY8 | c.354C>T p.A118= | Silent (SNP) | VAF 464/707 reads (66%) | called by muse, mutect2, varscan2
- AEBP1 | c.2079G>A p.E693= | Silent (SNP) | VAF 11/374 reads (3%) | called by muse, mutect2
- AK9 | c.1740G>A p.E580= | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- AKNA | c.1446C>T p.P482= | Silent (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- ANK1 | c.4131G>A p.R1377= | Silent (SNP) | VAF 48/540 reads (9%) | catalogued as rs1409012481; called by muse, mutect2
- ANK2 | c.7719T>C p.D2573= | Silent (SNP) | VAF 115/312 reads (37%) | called by muse, mutect2, varscan2
- ANK3 | c.5883C>T p.I1961= | Silent (SNP) | VAF 96/276 reads (35%) | called by muse, mutect2, varscan2
- ANKFY1 | c.705C>T p.F235= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- ANKLE1 | c.346C>T p.L116= (on ENST00000394458; = p.L62= on NM_152363.6) | Silent (SNP) | VAF 20/448 reads (4%) | catalogued as rs1394416892; called by muse, mutect2
- ARHGAP22 | c.1293C>T p.S431= | Silent (SNP) | VAF 17/648 reads (3%) | catalogued as COSV50943745; called by muse, mutect2
- ARHGDIA | c.141C>T p.S47= | Silent (SNP) | VAF 19/479 reads (4%) | called by muse, mutect2
- ARMC4 | c.60C>T p.I20= | Silent (SNP) | VAF 116/341 reads (34%) | catalogued as rs778962675; called by muse, mutect2, varscan2
- ASPHD2 | c.711G>T p.G237= | Silent (SNP) | VAF 16/640 reads (3%) | called by muse, mutect2
- BCL2L1 | c.18G>A p.R6= | Silent (SNP) | VAF 11/280 reads (4%) | called by muse, mutect2
- BHMT2 | c.609C>T p.I203= | Silent (SNP) | VAF 94/255 reads (37%) | catalogued as COSV99669955; called by muse, mutect2, varscan2
- BLOC1S4 | c.255G>A p.L85= | Silent (SNP) | VAF 165/407 reads (41%) | called by muse, mutect2, varscan2
- BMP2 | c.93G>A p.R31= | Silent (SNP) | VAF 207/499 reads (41%) | catalogued as rs1291679886, COSV66577964; called by muse, mutect2, varscan2
- BMP6 | c.15G>A p.G5= | Silent (SNP) | VAF 19/532 reads (4%) | called by muse, mutect2
- BTLA | c.51C>T p.F17= | Silent (SNP) | VAF 87/272 reads (32%) | called by muse, mutect2, varscan2
- C10orf71 | c.528C>T p.F176= | Silent (SNP) | VAF 150/381 reads (39%) | catalogued as rs768871388, COSV60510795; called by muse, mutect2, varscan2
- C12orf56 | c.1860G>A p.L620= (on ENST00000543942 / NM_001170633.2; = p.L460= on NM_001099676.3) | Silent (SNP) | VAF 34/1032 reads (3%) | called by muse, mutect2
- C1QB | c.693G>A p.L231= | Silent (SNP) | VAF 136/368 reads (37%) | catalogued as rs1430379014; called by muse, mutect2, varscan2
- CA4 | c.735C>T p.H245= | Silent (SNP) | VAF 97/254 reads (38%) | called by muse, mutect2, varscan2
- CASS4 | c.1758C>T p.L586= | Silent (SNP) | VAF 94/262 reads (36%) | called by muse, mutect2, varscan2
- CCDC168 | c.11376G>A p.K3792= | Silent (SNP) | VAF 67/185 reads (36%) | called by muse, mutect2, varscan2
- CCDC24 | c.15C>T p.S5= | Silent (SNP) | VAF 208/537 reads (39%) | called by muse, mutect2, varscan2
- CD8B | c.411C>T p.F137= | Silent (SNP) | VAF 9/294 reads (3%) | called by muse, mutect2
- CEACAM6 | c.873G>A p.V291= | Silent (SNP) | VAF 143/371 reads (39%) | catalogued as rs1555821984; called by mutect2, varscan2
- CHST1 | c.696G>A p.L232= | Silent (SNP) | VAF 23/519 reads (4%) | called by muse, mutect2
- CLEC16A | c.663C>T p.S221= | Silent (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- COL11A1 | c.4851C>T p.F1617= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV62173713; called by muse, mutect2, varscan2
- COL2A1 | c.2109C>T p.F703= | Silent (SNP) | VAF 126/547 reads (23%) | catalogued as COSV61528231; called by muse, mutect2, varscan2
- COL4A3 | c.3549G>A p.G1183= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as COSV59259519; called by muse, mutect2
- COL6A6 | c.45T>A p.I15= | Silent (SNP) | VAF 32/245 reads (13%) | catalogued as COSV62036697; called by muse, mutect2, varscan2
- CTDP1 | c.1392C>T p.S464= | Silent (SNP) | VAF 28/632 reads (4%) | catalogued as rs773179841, COSV99310238; called by muse, mutect2
- CYP11B1 | c.789C>T p.I263= | Silent (SNP) | VAF 323/541 reads (60%) | called by muse, mutect2, varscan2
- DAB1 | c.33G>A p.V11= | Silent (SNP) | VAF 82/283 reads (29%) | called by muse, mutect2, varscan2
- DCLK3 | c.1890C>T p.P630= | Silent (SNP) | VAF 146/419 reads (35%) | called by muse, mutect2, varscan2
- DDX60L | c.2826C>T p.L942= | Silent (SNP) | VAF 94/257 reads (37%) | catalogued as rs1268507024; called by muse, mutect2, varscan2
- DECR1 | c.522C>T p.F174= | Silent (SNP) | VAF 373/553 reads (67%) | catalogued as rs143170054; called by muse, mutect2, varscan2
- DISP1 | c.1362C>T p.L454= | Silent (SNP) | VAF 28/482 reads (6%) | called by muse, mutect2
- DISP1 | c.2118C>T p.F706= | Silent (SNP) | VAF 314/572 reads (55%) | catalogued as rs201599231, COSV52657743; called by muse, mutect2, varscan2
- DMBT1 | c.7386C>T p.S2462= (on ENST00000338354 / NM_001377530.1; = p.S1705= on NM_004406.3) | Silent (SNP) | VAF 26/244 reads (11%) | catalogued as COSV100353532; called by muse, varscan2
- DNAH3 | c.7764G>A p.T2588= | Silent (SNP) | VAF 110/477 reads (23%) | catalogued as COSV54506847; called by muse, mutect2, varscan2
- DNAH6 | c.5796C>T p.F1932= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs1245096266; called by muse, mutect2, varscan2
- DPP7 | c.1371C>T p.S457= | Silent (SNP) | VAF 149/302 reads (49%) | catalogued as rs368154419; called by muse, mutect2, varscan2
- DRC7 | c.1299G>A p.P433= | Silent (SNP) | VAF 83/239 reads (35%) | catalogued as rs778359316, COSV61053675; called by muse, mutect2, varscan2
- DYNAP | c.174C>T p.S58= (on ENST00000321600; = p.S32= on NM_173629.3) | Silent (SNP) | VAF 98/246 reads (40%) | catalogued as rs1282329041; called by muse, mutect2, varscan2
- DYSF | c.5304G>A p.R1768= | Silent (SNP) | VAF 50/490 reads (10%) | catalogued as rs1379550901; called by muse, mutect2, varscan2
- EDEM3 | c.423C>T p.V141= | Silent (SNP) | VAF 91/193 reads (47%) | catalogued as rs752453480, COSV58927347; called by muse, mutect2, varscan2
- EFL1 | c.645G>A p.L215= | Silent (SNP) | VAF 40/388 reads (10%) | called by muse, mutect2, varscan2
- EPC2 | c.489G>C p.L163= | Silent (SNP) | VAF 112/271 reads (41%) | called by muse, mutect2, varscan2
- EPHA6 | c.462C>T p.I154= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as COSV67567157; called by muse, mutect2, varscan2
- EXPH5 | c.3669G>A p.G1223= | Silent (SNP) | VAF 121/306 reads (40%) | called by mutect2, varscan2
- FAM90A26 | c.1164G>A p.G388= | Silent (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- FAT4 | c.14163G>A p.R4721= | Silent (SNP) | VAF 131/317 reads (41%) | catalogued as COSV100630541; called by muse, mutect2, varscan2
- FBXL12 | c.954C>T p.P318= | Silent (SNP) | VAF 107/264 reads (41%) | called by muse, mutect2, varscan2
- FBXW9 | c.804C>T p.I268= (on ENST00000587955; = p.I278= on NM_032301.3) | Silent (SNP) | VAF 108/271 reads (40%) | called by muse, varscan2
- FLII | c.163C>T p.L55= | Silent (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- FLT1 | c.2754C>T p.S918= | Silent (SNP) | VAF 74/221 reads (33%) | called by muse, mutect2, varscan2
- FMO3 | c.1524T>A p.P508= | Silent (SNP) | VAF 239/462 reads (52%) | called by muse, mutect2, varscan2
- FSHR | c.1158C>T p.I386= | Silent (SNP) | VAF 139/344 reads (40%) | catalogued as COSV58619860; called by muse, mutect2, varscan2
- FSIP2 | c.741T>C p.L247= | Silent (SNP) | VAF 77/227 reads (34%) | called by muse, varscan2
- GABBR2 | c.1164C>T p.F388= | Silent (SNP) | VAF 17/364 reads (5%) | called by muse, mutect2
- GALNT12 | c.837C>T p.F279= | Silent (SNP) | VAF 48/267 reads (18%) | catalogued as rs754951224, COSV66663775; called by muse, mutect2, varscan2
- GBP2 | c.378C>T p.F126= | Silent (SNP) | VAF 91/269 reads (34%) | catalogued as rs148121752; called by muse, mutect2, varscan2
- GDF2 | c.792G>A p.G264= | Silent (SNP) | VAF 113/350 reads (32%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1095G>A p.E365= | Silent (SNP) | VAF 117/1118 reads (10%) | called by muse, varscan2
- GPR45 | c.355C>T p.L119= | Silent (SNP) | VAF 53/372 reads (14%) | catalogued as rs1430283715; called by muse, mutect2, varscan2
- GPR63 | c.117C>T p.D39= | Silent (SNP) | VAF 22/235 reads (9%) | called by muse, mutect2
- GREB1L | c.4014C>T p.F1338= | Silent (SNP) | VAF 136/361 reads (38%) | called by muse, mutect2, varscan2
- HCRTR2 | c.1179G>A p.R393= | Silent (SNP) | VAF 268/397 reads (68%) | called by muse, mutect2, varscan2
- HDAC10 | c.1059C>T p.H353= | Silent (SNP) | VAF 253/443 reads (57%) | called by muse, mutect2, varscan2
- HTR1D | c.207C>T p.L69= | Silent (SNP) | VAF 155/451 reads (34%) | called by muse, mutect2, varscan2
- HTRA1 | c.804C>T p.G268= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- IGHD2-21 | c.27C>T p.F9= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- INTS1 | c.3075C>T p.G1025= | Silent (SNP) | VAF 164/438 reads (37%) | catalogued as rs1446262693; called by muse, mutect2, varscan2
- IZUMO1R | c.516C>T p.F172= (on ENST00000440961; = p.F179= on NM_001199206.3) | Silent (SNP) | VAF 68/479 reads (14%) | catalogued as rs878924763; called by muse, mutect2, varscan2
- KALRN | c.2670C>T p.L890= | Silent (SNP) | VAF 101/280 reads (36%) | catalogued as COSV99563575; called by muse, mutect2, varscan2
- KAT8 | c.861C>T p.I287= | Silent (SNP) | VAF 130/323 reads (40%) | catalogued as rs1225645245; called by muse, mutect2, varscan2
- KCNA5 | c.1485C>T p.I495= | Silent (SNP) | VAF 304/596 reads (51%) | catalogued as rs764615241, COSV52906566, COSV52907574; called by muse, mutect2, varscan2
- KCNB2 | c.847C>T p.L283= | Silent (SNP) | VAF 149/794 reads (19%) | called by muse, mutect2, varscan2
- KCNMB2 | c.102G>A p.R34= | Silent (SNP) | VAF 20/326 reads (6%) | catalogued as COSV64201022; called by muse, mutect2
- KIF2B | c.1239C>T p.S413= | Silent (SNP) | VAF 145/398 reads (36%) | called by muse, mutect2
- KIRREL2 | c.1443G>A p.R481= | Silent (SNP) | VAF 14/481 reads (3%) | called by muse, mutect2
- KLK13 | c.711C>T p.F237= | Silent (SNP) | VAF 163/441 reads (37%) | catalogued as COSV50067036; called by muse, mutect2, varscan2
- KLRF1 | c.315G>A p.S105= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2, varscan2
- KRT20 | c.1194G>A p.R398= | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- KRT77 | c.1137G>A p.K379= | Silent (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- LAMA3 | c.7714C>T p.L2572= (on ENST00000313654 / NM_198129.4; = p.L963= on NM_000227.6) | Silent (SNP) | VAF 109/310 reads (35%) | called by muse, mutect2, varscan2
- LARGE2 | c.747C>T p.A249= | Silent (SNP) | VAF 24/392 reads (6%) | called by muse, mutect2
- LCA5 | c.2055T>C p.D685= | Silent (SNP) | VAF 85/372 reads (23%) | catalogued as rs1389386479; called by muse, mutect2, varscan2
- LCE3A | c.111G>A p.G37= | Silent (SNP) | VAF 285/580 reads (49%) | catalogued as COSV59550484; called by muse, mutect2, varscan2
- LGSN | c.915G>A p.E305= | Silent (SNP) | VAF 34/1044 reads (3%) | called by muse, mutect2
- LOXHD1 | c.1464G>A p.K488= | Silent (SNP) | VAF 140/372 reads (38%) | called by muse, mutect2, varscan2
- MAGEB6B | c.861C>T p.L287= | Silent (SNP) | VAF 140/193 reads (73%) | called by muse, mutect2, varscan2
- MAPT | c.1962C>T p.S654= (on ENST00000262410 / NM_001377265.1; = p.S262= on NM_005910.5) | Silent (SNP) | VAF 172/458 reads (38%) | called by muse, mutect2, varscan2
- MGAM | c.948C>T p.S316= | Silent (SNP) | VAF 130/306 reads (42%) | called by muse, mutect2, varscan2
- MGAM2 | c.4848C>T p.I1616= | Silent (SNP) | VAF 120/334 reads (36%) | called by muse, mutect2, varscan2
- MMP20 | c.333C>T p.F111= | Silent (SNP) | VAF 104/289 reads (36%) | called by muse, mutect2, varscan2
- MORC1 | c.2649G>A p.R883= | Silent (SNP) | VAF 54/173 reads (31%) | catalogued as COSV51723817; called by muse, mutect2, varscan2
- MROH2B | c.1305C>A p.V435= | Silent (SNP) | VAF 34/381 reads (9%) | called by muse, mutect2
- MS4A6A | c.192C>T p.I64= | Silent (SNP) | VAF 13/475 reads (3%) | catalogued as COSV60621027; called by muse, mutect2
- MTHFD2L | c.1044G>A p.*348= (on ENST00000395759 / NM_001144978.2; = p.*290= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 73/235 reads (31%) | called by muse, mutect2, varscan2
- MUC16 | c.38091C>T p.L12697= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as rs771127807; called by muse, varscan2
- MUC16 | c.10104C>T p.I3368= | Silent (SNP) | VAF 19/437 reads (4%) | catalogued as rs1410733515; called by muse, mutect2
- MYADML2 | c.537C>T p.F179= | Silent (SNP) | VAF 40/587 reads (7%) | catalogued as rs1029756332, COSV57998920; called by muse, mutect2
- MYH13 | c.96C>T p.F32= | Silent (SNP) | VAF 136/409 reads (33%) | catalogued as rs189377998, COSV52823274; called by muse, mutect2, varscan2
- MYH2 | c.2517C>T p.F839= | Silent (SNP) | VAF 32/403 reads (8%) | catalogued as rs1489105001; called by muse, mutect2
- MYH4 | c.3411G>A p.E1137= | Silent (SNP) | VAF 119/381 reads (31%) | called by muse, mutect2, varscan2
- MYO9B | c.2817C>T p.F939= | Silent (SNP) | VAF 27/229 reads (12%) | catalogued as COSV68280038; called by muse, mutect2, varscan2
- NARS1 | c.1033C>T p.L345= | Silent (SNP) | VAF 122/344 reads (35%) | catalogued as rs1008790123, COSV56876530; called by muse, mutect2, varscan2
- NELL1 | c.1128G>A p.K376= | Silent (SNP) | VAF 113/326 reads (35%) | called by muse, mutect2, varscan2
- NFATC1 | c.603G>A p.Q201= | Silent (SNP) | VAF 213/530 reads (40%) | called by muse, mutect2, varscan2
- NLRP10 | c.1237C>T p.L413= | Silent (SNP) | VAF 205/509 reads (40%) | catalogued as rs545999929, COSV60778431; called by muse, mutect2, varscan2
- NONO | c.354C>T p.T118= | Silent (SNP) | VAF 110/161 reads (68%) | called by muse, mutect2, varscan2
- NOP58 | c.312C>T p.L104= | Silent (SNP) | VAF 83/222 reads (37%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6321C>T p.S2107= | Silent (SNP) | VAF 276/758 reads (36%) | catalogued as rs1362262402; called by muse, mutect2
- NPC1L1 | c.2331C>T p.G777= | Silent (SNP) | VAF 111/277 reads (40%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1215C>T p.F405= | Silent (SNP) | VAF 19/406 reads (5%) | catalogued as COSV56924153; called by muse, mutect2
- NUMA1 | c.1146C>T p.I382= | Silent (SNP) | VAF 114/284 reads (40%) | called by muse, mutect2, varscan2
- NUP107 | c.1062C>T p.I354= | Silent (SNP) | VAF 27/716 reads (4%) | catalogued as COSV99971907; called by muse, mutect2
- OAZ3 | c.252G>A p.E84= | Silent (SNP) | VAF 275/500 reads (55%) | called by muse, mutect2, varscan2
- OGDHL | c.2001G>A p.R667= | Silent (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- OR1L4 | c.717C>T p.F239= | Silent (SNP) | VAF 27/295 reads (9%) | called by muse, mutect2
- OR1L6 | c.825C>T p.F275= (on ENST00000373684; = p.F239= on NM_001004453.2) | Silent (SNP) | VAF 76/199 reads (38%) | called by muse, mutect2
- OR2AJ1 | c.969C>T p.F323= | Silent (SNP) | VAF 59/264 reads (22%) | catalogued as rs1371241010; called by muse, mutect2, varscan2
- OR4C6 | c.222C>T p.V74= | Silent (SNP) | VAF 145/386 reads (38%) | catalogued as rs532171134; called by muse, mutect2, varscan2
- OR4X1 | c.684G>A p.L228= | Silent (SNP) | VAF 137/382 reads (36%) | catalogued as rs1467291041, COSV60723658; called by muse, mutect2, varscan2
- OR51A4 | c.294C>T p.A98= | Silent (SNP) | VAF 148/883 reads (17%) | called by muse, mutect2
- OR51I1 | c.696C>T p.S232= | Silent (SNP) | VAF 148/434 reads (34%) | catalogued as COSV66508125; called by muse, mutect2
- OR5AK2 | c.702G>A p.R234= | Silent (SNP) | VAF 121/348 reads (35%) | catalogued as rs780254019, COSV58803826; called by muse, mutect2, varscan2
- OR5D18 | c.561C>T p.S187= | Silent (SNP) | VAF 55/346 reads (16%) | catalogued as rs1347293495, COSV61738654; called by muse, mutect2, varscan2
- OR5K4 | c.429G>A p.R143= | Silent (SNP) | VAF 107/313 reads (34%) | called by muse, mutect2, varscan2
- OR6C68 | c.657C>T p.I219= | Silent (SNP) | VAF 79/428 reads (18%) | catalogued as rs1242258395; called by muse, varscan2
- OR8D1 | c.343C>T p.L115= | Silent (SNP) | VAF 55/444 reads (12%) | catalogued as rs777912356, COSV100766493, COSV63442538; called by muse, mutect2, varscan2
- OR8J3 | c.879G>A p.R293= | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as COSV56880768; called by muse, mutect2, varscan2
- P4HTM | c.771C>T p.F257= | Silent (SNP) | VAF 105/328 reads (32%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1776G>A p.A592= | Silent (SNP) | VAF 122/343 reads (36%) | catalogued as rs1199530922, COSV65344279; called by muse, mutect2, varscan2
- PCDHA8 | c.1005C>T p.T335= | Silent (SNP) | VAF 85/278 reads (31%) | catalogued as rs1406099374; called by muse, mutect2, varscan2
- PCDHB2 | c.639C>T p.T213= | Silent (SNP) | VAF 135/337 reads (40%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1572G>A p.E524= | Silent (SNP) | VAF 284/694 reads (41%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1965C>T p.S655= | Silent (SNP) | VAF 145/443 reads (33%) | catalogued as rs1266729746; called by muse, mutect2, varscan2
- PCDHGB6 | c.1356C>T p.F452= | Silent (SNP) | VAF 150/397 reads (38%) | catalogued as COSV53905671; called by muse, mutect2, varscan2
- PCSK5 | c.822G>A p.P274= | Silent (SNP) | VAF 137/289 reads (47%) | catalogued as rs200775960, COSV65099377; called by muse, mutect2, varscan2
- PDE1C | c.216T>G p.L72= | Silent (SNP) | VAF 78/253 reads (31%) | called by muse, mutect2, varscan2
- PDE4A | c.1749C>T p.L583= (on ENST00000380702 / NM_001111307.2; = p.L344= on NM_006202.3) | Silent (SNP) | VAF 15/304 reads (5%) | catalogued as COSV99535095; called by muse, mutect2
- PGAP4 | c.172C>T p.L58= | Silent (SNP) | VAF 17/320 reads (5%) | called by muse, mutect2
- PKHD1 | c.11931C>T p.S3977= | Silent (SNP) | VAF 69/686 reads (10%) | catalogued as rs368081890; called by muse, mutect2
- PLCB1 | c.1494G>A p.E498= | Silent (SNP) | VAF 109/319 reads (34%) | catalogued as rs1182816630; called by muse, mutect2, varscan2
- PLEKHG4B | c.195C>T p.P65= (on ENST00000283426; = p.P421= on NM_052909.5) | Silent (SNP) | VAF 146/404 reads (36%) | catalogued as rs1291196899; called by muse, mutect2, varscan2
- PNPLA3 | c.1206C>T p.L402= | Silent (SNP) | VAF 231/441 reads (52%) | catalogued as rs754844289, COSV99337379; called by muse, mutect2, varscan2
- PNPLA7 | c.1533C>T p.I511= | Silent (SNP) | VAF 65/331 reads (20%) | catalogued as rs563010262; called by muse, mutect2, varscan2
- PPARD | c.1167C>T p.H389= | Silent (SNP) | VAF 76/898 reads (8%) | called by muse, mutect2
- PRAMEF1 | c.504C>T p.F168= | Silent (SNP) | VAF 82/331 reads (25%) | catalogued as rs2790782, COSV60018103; called by muse, mutect2, varscan2
- PRKACG | c.552G>A p.T184= | Silent (SNP) | VAF 151/329 reads (46%) | catalogued as COSV55252209, COSV55253585; called by muse, mutect2, varscan2
- PRKCA | c.1116G>A p.K372= | Silent (SNP) | VAF 113/322 reads (35%) | called by muse, mutect2, varscan2
- PRR23A | c.426C>T p.F142= | Silent (SNP) | VAF 138/400 reads (35%) | called by muse, mutect2
- PRR5-ARHGAP8 | c.1197C>T p.P399= (on ENST00000352766; = p.P320= on NM_181334.5) | Silent (SNP) | VAF 46/568 reads (8%) | called by muse, mutect2
- PTGR1 | c.681C>T p.I227= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as rs746335491; called by muse, mutect2, varscan2
- R3HDM1 | c.3183C>T p.S1061= | Silent (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- RAPGEFL1 | c.1506C>T p.I502= | Silent (SNP) | VAF 99/279 reads (35%) | catalogued as rs771923732; called by muse, mutect2, varscan2
- RASA1 | c.3024A>G p.E1008= | Silent (SNP) | VAF 22/345 reads (6%) | catalogued as CD1311735; called by muse, mutect2
- RASA2 | c.804C>T p.F268= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- RASGRP2 | c.1021C>T p.L341= | Silent (SNP) | VAF 176/468 reads (38%) | called by muse, mutect2, varscan2
- RBMXL2 | c.582G>A p.P194= | Silent (SNP) | VAF 146/366 reads (40%) | catalogued as rs980083360, COSV60978388; called by muse, mutect2, varscan2
- RBMXL3 | c.2640C>T p.A880= | Silent (SNP) | VAF 223/275 reads (81%) | catalogued as rs1028378235; called by muse, mutect2, varscan2
- REPIN1 | c.1377C>T p.F459= | Silent (SNP) | VAF 219/586 reads (37%) | catalogued as rs747203084, COSV101262667; called by muse, mutect2, varscan2
- RFC4 | c.1044C>A p.L348= | Silent (SNP) | VAF 94/259 reads (36%) | catalogued as COSV56217090, COSV99961279; called by muse, mutect2, varscan2
- RGL1 | c.2052G>A p.L684= (on ENST00000360851 / NM_001297672.2; = p.L719= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/570 reads (4%) | called by muse, mutect2
- RP1 | c.498G>A p.T166= | Silent (SNP) | VAF 172/427 reads (40%) | catalogued as rs267601947, COSV55123109; called by muse, mutect2, varscan2
- RTL1 | c.3000G>A p.R1000= | Silent (SNP) | VAF 165/386 reads (43%) | called by muse, mutect2, varscan2
- RTL1 | c.2631G>A p.L877= | Silent (SNP) | VAF 146/417 reads (35%) | called by muse, mutect2, varscan2
- RTN3 | c.1404G>A p.V468= (on ENST00000377819 / NM_001265589.2; = p.V449= on NM_201428.3) | Silent (SNP) | VAF 120/320 reads (38%) | called by muse, mutect2, varscan2
- RWDD2B | c.237A>G p.R79= | Silent (SNP) | VAF 15/401 reads (4%) | called by muse, mutect2
- SARDH | c.1845G>A p.G615= | Silent (SNP) | VAF 21/393 reads (5%) | called by muse, mutect2
- SCFD2 | c.1812C>T p.L604= | Silent (SNP) | VAF 134/332 reads (40%) | catalogued as COSV66377280; called by muse, mutect2, varscan2
- SCN10A | c.5394C>T p.I1798= | Silent (SNP) | VAF 139/398 reads (35%) | catalogued as COSV71860754; called by muse, mutect2, varscan2
- SCN4A | c.2415C>T p.F805= | Silent (SNP) | VAF 86/226 reads (38%) | catalogued as rs1275520070; called by muse, mutect2, varscan2
- SCN9A | c.2649C>T p.V883= (on ENST00000303354; = p.V872= on NM_002977.3) | Silent (SNP) | VAF 131/394 reads (33%) | catalogued as rs200618289; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SELE | c.1461C>T p.S487= | Silent (SNP) | VAF 92/307 reads (30%) | catalogued as rs1027899696; called by muse, mutect2, varscan2
- SF3B3 | c.345C>T p.I115= | Silent (SNP) | VAF 126/341 reads (37%) | catalogued as rs773652279; called by muse, mutect2, varscan2
- SH3TC1 | c.1794C>T p.F598= | Silent (SNP) | VAF 153/394 reads (39%) | catalogued as COSV55281172; called by muse, mutect2, varscan2
- SHC3 | c.738G>A p.A246= | Silent (SNP) | VAF 43/277 reads (16%) | catalogued as rs1371077393; called by muse, mutect2, varscan2
- SHKBP1 | c.1563C>T p.F521= | Silent (SNP) | VAF 150/354 reads (42%) | catalogued as rs150936292; called by muse, mutect2, varscan2
- SIRPB2 | c.876C>T p.F292= | Silent (SNP) | VAF 102/259 reads (39%) | catalogued as rs751120893; called by muse, mutect2
- SLC1A3 | c.246C>T p.S82= | Silent (SNP) | VAF 18/384 reads (5%) | catalogued as COSV54318284; called by muse, mutect2
- SLC22A25 | c.1137C>T p.F379= | Silent (SNP) | VAF 54/371 reads (15%) | catalogued as COSV60596129; called by muse, mutect2, varscan2
- SLC28A3 | c.420C>T p.F140= | Silent (SNP) | VAF 55/341 reads (16%) | called by muse, mutect2, varscan2
- SLC34A2 | c.1071C>T p.F357= | Silent (SNP) | VAF 90/240 reads (38%) | catalogued as rs765763683, COSV101158194; called by muse, mutect2, varscan2
- SLC35C2 | c.498C>T p.F166= | Silent (SNP) | VAF 153/429 reads (36%) | catalogued as rs767328554, COSV99709134; called by muse, mutect2, varscan2
- SLC4A1 | c.846C>T p.G282= | Silent (SNP) | VAF 34/281 reads (12%) | catalogued as rs1399970291; called by muse, mutect2, varscan2
- SLC5A9 | c.469C>T p.L157= | Silent (SNP) | VAF 113/307 reads (37%) | called by muse, mutect2, varscan2
- SLC6A18 | c.1563G>A p.R521= | Silent (SNP) | VAF 153/494 reads (31%) | called by muse, mutect2, varscan2
- SLC6A5 | c.447G>A p.V149= | Silent (SNP) | VAF 148/426 reads (35%) | called by muse, mutect2
- SLIT1 | c.3012G>A p.V1004= | Silent (SNP) | VAF 123/359 reads (34%) | called by muse, mutect2, varscan2
- SNCAIP | c.948G>A p.L316= | Silent (SNP) | VAF 101/292 reads (35%) | catalogued as COSV54410735; called by muse, mutect2, varscan2
- SOCS1 | c.610C>T p.L204= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as COSV59660385; called by muse, mutect2
- SPEG | c.1869G>A p.T623= | Silent (SNP) | VAF 26/532 reads (5%) | catalogued as rs1389064070; called by muse, mutect2
- SPTBN4 | c.5754G>A p.Q1918= | Silent (SNP) | VAF 131/431 reads (30%) | catalogued as COSV58943488; called by muse, mutect2, varscan2
- SRCAP | c.4645C>T p.L1549= | Silent (SNP) | VAF 178/462 reads (39%) | called by muse, mutect2, varscan2
- SRRM2 | c.3606C>T p.F1202= | Silent (SNP) | VAF 151/398 reads (38%) | catalogued as rs758991436, COSV57069576; called by muse, mutect2, varscan2
- SSPN | c.507G>A p.S169= | Silent (SNP) | VAF 150/661 reads (23%) | catalogued as rs149834431, COSV99658702; called by muse, mutect2, varscan2
- ST8SIA3 | c.510C>T p.I170= | Silent (SNP) | VAF 29/415 reads (7%) | catalogued as rs1201250222, COSV60655026; called by muse, mutect2
- STK26 | c.984C>T p.T328= | Silent (SNP) | VAF 22/197 reads (11%) | catalogued as rs1401895033, COSV100048880, COSV53746303; called by muse, mutect2, varscan2
- SUGCT | c.717C>T p.S239= | Silent (SNP) | VAF 23/201 reads (11%) | called by muse, mutect2, varscan2
- SUSD5 | c.186G>A p.K62= | Silent (SNP) | VAF 49/428 reads (11%) | called by muse, mutect2, varscan2
- SYNGR1 | c.129C>T p.I43= | Silent (SNP) | VAF 79/475 reads (17%) | catalogued as rs762377335, COSV53369509; called by muse, mutect2, varscan2
- TBX20 | c.141G>A p.E47= | Silent (SNP) | VAF 20/357 reads (6%) | called by muse, mutect2
- TCEAL6 | c.273G>A p.E91= | Silent (SNP) | VAF 264/359 reads (74%) | called by muse, mutect2, varscan2
- TDRD15 | c.531C>T p.L177= | Silent (SNP) | VAF 97/271 reads (36%) | catalogued as rs762699392; called by muse, mutect2, varscan2
- TDRD5 | c.1371G>A p.P457= | Silent (SNP) | VAF 246/495 reads (50%) | catalogued as rs184128732, COSV99675689; called by muse, mutect2, varscan2
- TEX15 | c.81G>A p.L27= (on ENST00000638951; = p.L23= on NM_001350162.2) | Silent (SNP) | VAF 138/214 reads (64%) | called by muse, mutect2, varscan2
- TEX2 | c.474C>T p.T158= | Silent (SNP) | VAF 165/417 reads (40%) | called by muse, mutect2, varscan2
- TFDP1 | c.1179C>T p.V393= | Silent (SNP) | VAF 128/344 reads (37%) | catalogued as rs143555000; called by muse, mutect2, varscan2
- TG | c.5910C>T p.F1970= | Silent (SNP) | VAF 40/724 reads (6%) | catalogued as COSV99602800; called by muse, mutect2
- TIMELESS | c.1179C>T p.S393= | Silent (SNP) | VAF 145/371 reads (39%) | called by muse, mutect2, varscan2
- TJP1 | c.4947C>T p.S1649= | Silent (SNP) | VAF 178/489 reads (36%) | called by muse, mutect2, varscan2
- TM6SF2 | c.261C>T p.S87= | Silent (SNP) | VAF 39/414 reads (9%) | called by muse, mutect2
- TM9SF4 | c.1236A>T p.G412= | Silent (SNP) | VAF 122/315 reads (39%) | called by muse, mutect2, varscan2
- TMCO2 | c.435G>A p.G145= | Silent (SNP) | VAF 109/334 reads (33%) | called by muse, mutect2, varscan2
- TMEM214 | c.1108C>T p.L370= | Silent (SNP) | VAF 134/348 reads (39%) | catalogued as rs749530106; called by muse, varscan2
- TMEM63B | c.879G>A p.R293= | Silent (SNP) | VAF 17/485 reads (4%) | called by muse, mutect2
- TMPRSS13 | c.396C>T p.I132= | Silent (SNP) | VAF 146/397 reads (37%) | catalogued as rs1386813368; called by muse, mutect2, varscan2
- TMPRSS7 | c.195G>A p.K65= | Silent (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- TNFRSF11B | c.525G>A p.Q175= | Silent (SNP) | VAF 136/729 reads (19%) | catalogued as COSV52069022, COSV52074058; called by muse, mutect2, varscan2
- TPM3 | c.123G>A p.E41= | Silent (SNP) | VAF 18/313 reads (6%) | called by muse, mutect2
- TRIM44 | c.66G>A p.E22= | Silent (SNP) | VAF 172/418 reads (41%) | called by muse, mutect2, varscan2
- TRPC7 | c.2376C>T p.V792= | Silent (SNP) | VAF 22/436 reads (5%) | called by muse, mutect2
- TRUB1 | c.24G>C p.V8= | Silent (SNP) | VAF 26/297 reads (9%) | catalogued as rs748901670, COSV53930356, COSV53931364; called by muse, mutect2
- UBA7 | c.675C>T p.P225= | Silent (SNP) | VAF 103/278 reads (37%) | called by muse, mutect2, varscan2
- UBXN11 | c.183C>A p.A61= | Silent (SNP) | VAF 132/317 reads (42%) | called by muse, mutect2, varscan2
- UNC45B | c.831G>A p.Q277= | Silent (SNP) | VAF 49/297 reads (16%) | called by muse, mutect2, varscan2
- UPK3B | c.219C>T p.S73= | Silent (SNP) | VAF 185/680 reads (27%) | catalogued as rs762477512, COSV56860297; called by muse, mutect2, varscan2
- USP6 | c.3615G>A p.G1205= | Silent (SNP) | VAF 42/328 reads (13%) | called by muse, mutect2, varscan2
- WDFY4 | c.9369C>T p.S3123= | Silent (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
- WDR62 | c.1629C>T p.S543= | Silent (SNP) | VAF 16/476 reads (3%) | called by muse, mutect2
- WDR62 | c.4116C>T p.A1372= | Silent (SNP) | VAF 64/402 reads (16%) | called by muse, mutect2, varscan2
- XIRP2 | c.6471G>A p.E2157= (on ENST00000628543; = p.E2332= on NM_152381.6) | Silent (SNP) | VAF 144/390 reads (37%) | called by muse, mutect2, varscan2
- ZEB2 | c.2121C>T p.S707= | Silent (SNP) | VAF 15/388 reads (4%) | catalogued as COSV57952090; called by muse, mutect2
- ZNF185 | c.393C>T p.S131= | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- ZNF679 | c.195C>T p.I65= | Silent (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- ZNF827 | c.465C>T p.S155= | Silent (SNP) | VAF 129/376 reads (34%) | called by muse, mutect2, varscan2
- ZPLD1 | c.48G>A p.P16= (on ENST00000466937 / NM_001329788.1; = p.P32= on NM_175056.2) | Silent (SNP) | VAF 94/301 reads (31%) | catalogued as rs761304064, COSV60352749; called by muse, mutect2, varscan2
- ABR | c.1791+18362C>T | Intron (SNP) | VAF 171/402 reads (43%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700851 C>T | 3'Flank (SNP) | VAF 166/422 reads (39%) | called by muse, mutect2
- AP4S1 | c.306+24C>T | Intron (SNP) | VAF 101/297 reads (34%) | catalogued as COSV53555655; called by muse, mutect2, varscan2
- ARMC8 | c.1134+15G>A | Intron (SNP) | VAF 30/522 reads (6%) | called by muse, mutect2
- BRD2 | c.-1305+265C>T | Intron (SNP) | VAF 43/654 reads (7%) | called by muse, mutect2
- BRF1 | c.*948C>T | 3'UTR (SNP) | VAF 126/342 reads (37%) | catalogued as rs759189237; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990265 C>T | 5'Flank (SNP) | VAF 103/254 reads (41%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990565 T>A | 5'Flank (SNP) | VAF 124/345 reads (36%) | called by muse, mutect2, varscan2
- CD8B | c.621-6626C>T | Intron (SNP) | VAF 73/240 reads (30%) | called by muse, mutect2, varscan2
- CHST15 | c.*2149C>T | 3'UTR (SNP) | VAF 89/262 reads (34%) | called by muse, mutect2, varscan2
- GCNT1 | c.*1297C>T | 3'UTR (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- GLIS1 | c.-61G>A | 5'UTR (SNP) | VAF 154/404 reads (38%) | called by muse, mutect2, varscan2
- KCNK16 | c.802+56G>A | Intron (SNP) | VAF 357/521 reads (69%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.1139T>G | RNA (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- MEFV | c.1760-32G>A | Intron (SNP) | VAF 42/343 reads (12%) | called by muse, mutect2, varscan2
- PKD1L2 | c.2778+34C>T | Intron (SNP) | VAF 146/266 reads (55%) | called by muse, mutect2, varscan2
- PRORY | n.222C>T | RNA (SNP) | VAF 64/215 reads (30%) | catalogued as rs1297330653; called by muse, mutect2, varscan2
- PRORY | n.221T>G | RNA (SNP) | VAF 64/213 reads (30%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49594832 C>T | 5'Flank (SNP) | VAF 57/400 reads (14%) | catalogued as COSV55870372; called by muse, mutect2, varscan2
- RNF213 | c.10304-132C>T | Intron (SNP) | VAF 119/310 reads (38%) | catalogued as rs572086283, COSV60411559; called by muse, mutect2, varscan2
- STARD8 | c.-7-1063C>T | Intron (SNP) | VAF 14/194 reads (7%) | catalogued as COSV99366631; called by muse, mutect2
- SYNPO | chr5:150656618 C>T | 3'Flank (SNP) | VAF 135/433 reads (31%) | called by muse, mutect2, varscan2
- TREM1 | c.599+44C>T | Intron (SNP) | VAF 345/525 reads (66%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672772 G>A | 3'Flank (SNP) | VAF 176/345 reads (51%) | called by muse, mutect2
